Somatic mutation profile of tumor specimen 0DRMOK from CCDI case PBCGXF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,603 days).
Specimen 0DRMOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfa59306-c07f-41c1-a3c0-72a543e2f3fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRMON (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f89345f5-4cc8-44e3-aa06-8666623d7584

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 3, Silent 2, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX15 | c.2343C>G p.D781E | Missense Mutation (SNP) | VAF 259/610 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100391839; called by muse, mutect2, varscan2
- EML5 | c.3877G>T p.G1293C | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61341958; called by muse, mutect2
- FAM181A | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.914); catalogued as rs779754850; called by muse, mutect2
- TCAF2 | c.1086G>T p.Q362H | Missense Mutation (SNP) | VAF 220/731 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs768656027, COSV100633572; called by muse, mutect2, varscan2
- AC093246.1 | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 77/170 reads (45%) | called by muse, mutect2, varscan2
- BMPR1A | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 209/306 reads (68%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDCL2 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 185/404 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- SMC1B | c.1136A>T p.K379M | Missense Mutation (SNP) | VAF 203/462 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HPCAL1 | c.399G>A p.S133= | Silent (SNP) | VAF 130/324 reads (40%) | catalogued as rs370800820; called by muse, mutect2, varscan2
- IL16 | c.2820G>A p.P940= (on ENST00000302987 / NM_172217.5; = p.P239= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/318 reads (14%) | catalogued as rs769404703, COSV100267343, COSV57261464; called by muse, mutect2, varscan2
- DCTN1 | c.1854+40A>T | Intron (SNP) | VAF 145/289 reads (50%) | catalogued as rs745510395; called by muse, mutect2, varscan2
- KRTAP9-2 | c.*30del | 3'UTR (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
- PDZD11 | c.*50C>T | 3'UTR (SNP) | VAF 135/151 reads (89%) | called by muse, mutect2, varscan2
- SFTPB | c.-54G>A | 5'UTR (SNP) | VAF 54/95 reads (57%) | catalogued as rs34024265; called by muse, mutect2, varscan2
- SGCE | c.1486+864T>C | Intron (SNP) | VAF 166/398 reads (42%) | called by muse, mutect2, varscan2
- SKP2 | c.8+34del | Intron (DEL) | VAF 76/203 reads (37%) | called by mutect2, pindel, varscan2
